Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A02G, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A02G-01A (Primary Tumor).

Diagnosis:

The findings under I are the liver metastasis of an adenocarcinoma (in this case, rectal carcinoma corresponding to pN1),

The findings under II show a free anastomosis ring

and in III a sigmoid rectum resection with an invasive rectal carcinoma (G2 to 3) with infiltration of the muscularis (pT2), with infiltration of blood vessels and lymph vessels (L1, V1) and with free resection margins and three lymph node metastases (pN1).

Comment:

The distance from the mesorectal fascia is over 1 cm

Tumor classification:

ICDO-DA M-8140/3

G2-3, pT2, L1, V1, pN1, pM1.

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: rectum c20.9 per 4/1/11

Review Initials	per [signature]	[signature]

Source: NCI Genomic Data Commons file dca3dbe6-92d2-498d-bb1d-875129350107 (TCGA-AG-A02G.FC49ABE9-B893-404C-9DF1-DDA94EB78F71.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).